Somatic mutation profile of tumor specimen TCGA-93-A4JQ-01A (aliquot TCGA-93-A4JQ-01A-11D-A24P-08) from TCGA case TCGA-93-A4JQ, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 49.1 years (17,951 days).
Specimen TCGA-93-A4JQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b04524a-cf78-42a9-90d4-fea652fa85b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-A4JQ-10A (Blood Derived Normal), aliquot TCGA-93-A4JQ-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/194031cc-b208-4b76-8185-9ac777cb242c

The open-access MAF lists 137 somatic variants for this specimen: 103 protein-altering or splice-affecting, 29 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 29, Nonsense Mutation 5, Splice Region 3, RNA 3, 5'Flank 1, Intron 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADAC | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV51759264, COSV51761122; called by muse, mutect2
- ABLIM3 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV100448066; called by muse, mutect2, varscan2
- ADAMTS5 | c.2111T>C p.V704A | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV99537035; called by muse, mutect2
- ANKLE2 | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV100513931; called by muse, mutect2, varscan2
- ANKS1B | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV100242979; called by muse, mutect2
- ARHGAP31 | c.3502G>A p.V1168I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99956600; called by muse, mutect2, varscan2
- ARHGAP32 | c.2219A>G p.N740S (on ENST00000310343 / NM_001378025.1; = p.N391S on NM_014715.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as rs149902728; called by muse, mutect2, varscan2
- ATP9A | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100124323; called by muse, mutect2, varscan2
- AZGP1 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.815); catalogued as COSV99447677; called by muse, mutect2
- BRINP3 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV66516533, COSV66525950; called by muse, mutect2
- CALCOCO2 | c.55C>G p.H19D | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV99363642; called by muse, mutect2
- CASKIN1 | c.1788G>A p.M596I | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100399077; called by muse, mutect2
- CCDC141 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV55375257; called by muse, mutect2
- CDH12 | c.868A>G p.R290G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV101203415; called by muse, mutect2
- CEP120 | c.352A>C p.K118Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100070810; called by muse, mutect2, varscan2
- CNTNAP4 | c.3754T>G p.F1252V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100269407; called by muse, mutect2, varscan2
- DCX | c.824A>G p.K275R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100576184; called by muse, mutect2, varscan2
- DDX46 | c.2268C>G p.F756L | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100844906; called by muse, mutect2
- DHX32 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs775776642, COSV99034461; called by muse, mutect2, varscan2
- DLG5 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); catalogued as rs779423863, COSV64946586; called by muse, mutect2, varscan2
- DNHD1 | c.13387C>G p.Q4463E | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.066); catalogued as COSV99599428; called by muse, mutect2
- DOCK4 | c.4566G>T p.E1522D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as COSV101447779; called by muse, mutect2, varscan2
- DOCK9 | c.4315C>G p.L1439V (on ENST00000376460 / NM_001366676.2; = p.L1440V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV100237971, COSV100240466; called by muse, mutect2, varscan2
- EIF3E | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV99622799; called by muse, mutect2, varscan2
- ERICH6 | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs755866281, COSV99901357; called by muse, mutect2
- FAM83B | c.2648A>G p.D883G | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV100174038; called by muse, mutect2
- FOXP2 | c.1579C>T p.L527F | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100646226; called by muse, mutect2
- FRY | c.7760A>C p.Q2587P | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.055); catalogued as COSV100968804; called by muse, mutect2, varscan2
- FSIP1 | c.828G>C p.K276N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63225375; called by muse, mutect2
- GPR52 | c.1031A>C p.D344A | Missense Mutation (SNP) | VAF 5/132 reads (4%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as COSV99273407; called by muse, mutect2
- HEPH | c.2307C>A p.F769L (on ENST00000343002; = p.F502L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100294111; called by muse, mutect2, varscan2
- HFM1 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54036729; called by muse, mutect2
- IL3 | c.116T>C p.I39T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV99735205; called by muse, mutect2
- KLHL18 | c.792C>A p.H264Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); catalogued as COSV99230523; called by muse, mutect2
- KMT2C | c.7150-2A>C p.X2384_splice | Splice Site (SNP) | VAF 31/181 reads (17%) | catalogued as COSV100066949; called by muse, mutect2, varscan2
- LDLRAD4 | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV100761937; called by muse, mutect2
- LYST | c.7066G>C p.D2356H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1558194943, CD000247, COSV101088199; called by muse, mutect2, varscan2
- MDC1 | c.5029C>G p.Q1677E | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100902564, COSV64523010; called by muse, mutect2
- MGA | c.7855G>A p.V2619I (on ENST00000219905 / NM_001164273.1; = p.V2410I on NM_001080541.2) | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99578540; called by muse, mutect2
- MKI67 | c.1601C>A p.T534N | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as COSV100896169; called by muse, mutect2
- NCAPD3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV73258427; called by muse, mutect2
- NELL1 | c.606G>T p.G202= | Splice Region (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100119035; called by muse, mutect2, varscan2
- NEU2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs140090973; called by muse, mutect2
- NPBWR2 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 7/116 reads (6%) | catalogued as COSV100871079; called by muse, mutect2
- OR13J1 | c.368A>C p.Y123S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100940750; called by muse, mutect2
- OR1B1 | c.702G>C p.L234F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV100506405; called by muse, mutect2
- OR5H1 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV100641623, COSV100641667; called by muse, mutect2
- OR8I2 | c.254T>A p.F85Y | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100135855; called by muse, mutect2
- OR9G4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs371724362; called by muse, mutect2
- OTX2 | c.281G>A p.R94H (on ENST00000408990 / NM_172337.3; = p.R102H on NM_021728.4) | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV59766091; called by muse, mutect2, varscan2
- PARP9 | c.2380A>G p.S794G | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100830911; called by muse, mutect2
- PCDHA3 | c.1365C>A p.F455L | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100793156; called by muse, mutect2
- PDE6G | c.95A>G p.Q32R | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100148458; called by muse, mutect2
- PSAP | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206421; called by muse, mutect2, varscan2
- PSG8 | c.911A>T p.E304V | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100125983; called by muse, mutect2
- PSG8 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 22/270 reads (8%) | catalogued as COSV100125985; called by muse, mutect2
- PTH2R | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as COSV99782092; called by muse, mutect2, varscan2
- RAPGEF2 | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen possibly damaging (0.715); catalogued as rs373371689, COSV100030527; called by muse, mutect2, varscan2
- RNF113B | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.129); catalogued as COSV99940272; called by muse, mutect2
- RNH1 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100596654; called by muse, mutect2
- RRAGD | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV100784499; called by muse, mutect2, varscan2
- RYR2 | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63719400; called by muse, mutect2
- S100A11 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99643178; called by muse, mutect2
- SEC24C | c.2051C>G p.A684G | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as COSV100226517; called by muse, mutect2
- SELENOI | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as COSV99564187; called by muse, mutect2
- SH3TC1 | c.2120C>T p.S707L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV55282967, COSV99794416; called by muse, mutect2, varscan2
- SIGLECL1 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV57065028; called by muse, mutect2
- SIPA1L3 | c.2145G>C p.K715N | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55910177; called by muse, mutect2
- SLC30A10 | c.805A>T p.S269C | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV100751430; called by muse, mutect2
- SLK | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100211480; called by muse, mutect2, varscan2
- SORBS1 | c.538C>T p.P180S (on ENST00000361941 / NM_001034954.2; = p.P148S on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV99527431; called by muse, mutect2, varscan2
- SP110 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99283010; called by muse, mutect2
- STX2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55433898; called by muse, mutect2
- TARS2 | c.1527C>A p.D509E | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100945850; called by muse, mutect2
- TESK2 | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.186); catalogued as COSV100517063, COSV59149056; called by muse, mutect2
- TLR7 | c.2115C>A p.D705E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101027715; called by muse, mutect2, varscan2
- TMEM30A | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs983846586, COSV100034724; called by muse, mutect2
- TRPV5 | c.1809G>A p.M603I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV99520104; called by muse, mutect2
- UNC79 | c.6202A>C p.M2068L (on ENST00000393151 / NM_001346218.2; = p.M1891L on NM_020818.5) | Missense Mutation (SNP) | VAF 81/419 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.113); catalogued as COSV99825858; called by muse, mutect2, varscan2
- USP32 | c.1745G>C p.R582T | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100341438; called by muse, mutect2
- UTP20 | c.3712A>G p.I1238V | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs572010130, COSV99880807; called by muse, mutect2
- VWF | c.8053T>A p.F2685I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99777996; called by muse, mutect2, varscan2
- WASHC4 | c.1758A>T p.K586N | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV100162109; called by muse, mutect2
- XPNPEP2 | c.1365C>T p.Y455= | Splice Region (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100941401; called by muse, mutect2, varscan2
- XPOT | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100225340; called by muse, mutect2
- ZFAND4 | c.1598C>T p.S533L | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100762868; called by muse, mutect2
- ZNF549 | c.492G>C p.E164D (on ENST00000376233 / NM_001199295.2; = p.E151D on NM_153263.2) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV99558370; called by muse, mutect2
- ZNF616 | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as COSV100348086, COSV57513884; called by muse, mutect2
- ZNF638 | c.4226C>G p.S1409* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100038014; called by muse, mutect2
- AGGF1 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.397); called by muse, mutect2
- ASAH2 | c.1634C>G p.S545C | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BRCA1 | c.2345G>A p.S782N | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- C3orf35 | n.1369G>A | Splice Region (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- COL6A3 | c.5448G>T p.L1816F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXL6 | c.1155C>G p.N385K | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2
- GPR26 | c.917A>T p.K306M | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2
- IGBP1P2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- IGKV3D-7 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2
- MGA | c.7979A>G p.E2660G (on ENST00000219905 / NM_001164273.1; = p.E2451G on NM_001080541.2) | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2
- MRC1 | c.3336A>T p.Q1112H | Missense Mutation (SNP) | VAF 25/488 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.369); called by muse, mutect2
- PCDHB3 | c.1884G>T p.R628S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- RPTOR | c.3282G>T p.R1094S | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SIAH1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- ADCY10 | c.765G>A p.L255= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100896570; called by muse, mutect2, varscan2
- AK9 | c.831T>C p.F277= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV99572338; called by muse, mutect2, varscan2
- AKAP9 | c.2748C>G p.V916= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100661915; called by muse, mutect2
- BOP1 | c.1068C>T p.Y356= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1317078055; called by muse, mutect2
- CALCA | c.96G>C p.L32= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100523917; called by muse, mutect2, varscan2
- CAPSL | c.531C>T p.T177= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV101274166; called by muse, mutect2, varscan2
- DNAJC18 | c.456C>T p.F152= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV100122057; called by muse, mutect2
- GABBR2 | c.2508C>T p.D836= | Silent (SNP) | VAF 15/252 reads (6%) | catalogued as COSV52323104, COSV99409219; called by muse, mutect2
- H2BC9 | c.264G>C p.S88= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as rs1489147078, COSV55099128; called by muse, mutect2, varscan2
- IRF8 | c.1206C>G p.V402= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV51898776; called by muse, mutect2
- JAKMIP2 | c.1708T>C p.L570= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as COSV99507412; called by muse, mutect2
- LRRK2 | c.1485G>A p.E495= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV100109257, COSV104405970; called by muse, mutect2, varscan2
- NASP | c.136C>T p.L46= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100601605; called by muse, mutect2, varscan2
- OPRL1 | c.12C>G p.L4= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV100401943; called by muse, mutect2
- OR2M3 | c.672T>A p.A224= | Silent (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- PCGF2 | c.501A>G p.R167= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- PCYOX1L | c.783G>C p.V261= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- PI15 | c.75C>G p.L25= | Silent (SNP) | VAF 8/196 reads (4%) | catalogued as COSV99478019; called by muse, mutect2
- PNMA3 | c.882G>C p.L294= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100937551; called by muse, mutect2
- ROBO1 | c.3243A>G p.S1081= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as COSV101458299; called by muse, mutect2, varscan2
- RRAGD | c.171C>T p.F57= | Silent (SNP) | VAF 43/276 reads (16%) | catalogued as COSV100784500; called by muse, mutect2, varscan2
- SDAD1 | c.1950C>T p.N650= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100668551; called by muse, mutect2, varscan2
- SLC7A10 | c.1320C>T p.F440= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV53506755, COSV99471994; called by muse, mutect2
- SLC9A4 | c.504C>T p.I168= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99762704; called by muse, mutect2
- SOAT1 | c.903A>G p.L301= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV100858884; called by muse, mutect2, varscan2
- TGOLN2 | c.648T>C p.T216= | Silent (SNP) | VAF 20/330 reads (6%) | catalogued as rs879133627, COSV56405863; called by muse, mutect2
- TXNL1 | c.309C>A p.I103= | Silent (SNP) | VAF 7/144 reads (5%) | catalogued as COSV99469424, COSV99469956; called by muse, mutect2
- ZDHHC9 | c.708C>G p.L236= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100852114; called by muse, mutect2, varscan2
- ZER1 | c.1599G>A p.K533= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV99401836; called by muse, mutect2
- EXOC3 | chr5:442490 C>T | 5'Flank (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- PKD1L2 | n.854C>T | RNA (SNP) | VAF 8/95 reads (8%) | catalogued as rs1165501075; called by muse, mutect2
- SNORD116-20 | n.9G>A | RNA (SNP) | VAF 12/185 reads (6%) | called by muse, mutect2
- SSX6P | n.362T>A | RNA (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- TENM2 | c.503-120824C>G | Intron (SNP) | VAF 20/279 reads (7%) | catalogued as COSV101585438; called by muse, mutect2
